Somatic mutation profile of tumor specimen TCGA-AX-A2H4-01A (aliquot TCGA-AX-A2H4-01A-21D-A18P-09) from TCGA case TCGA-AX-A2H4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.3 years (24,234 days).
Specimen TCGA-AX-A2H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4040d05b-4679-4335-a2e1-d25c7cd2df94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2H4-11A (Solid Tissue Normal), aliquot TCGA-AX-A2H4-11A-11D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9728624-76fa-457e-aa3f-39084474af16

The open-access MAF lists 203 somatic variants for this specimen: 154 protein-altering or splice-affecting, 48 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 48, Nonsense Mutation 9, Frame Shift Del 3, Splice Region 2, 3'Flank 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 32/62 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 29/39 reads (74%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABLIM3 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs766297738, COSV100448694, COSV58646347; called by muse, mutect2, varscan2
- ACOX1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV99503898; called by muse, mutect2, varscan2
- ADAMTS3 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711830; called by muse, mutect2, varscan2
- ADAMTS9 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.216); catalogued as COSV99900022; called by muse, mutect2, varscan2
- AHSG | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99890262; called by mutect2, varscan2
- AMBP | c.80A>C p.D27A | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99469277; called by muse, mutect2, varscan2
- ANAPC1 | c.4783C>T p.H1595Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100595004; called by muse, mutect2, varscan2
- ARHGEF26 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs376134635; called by muse, mutect2, varscan2
- ARL8A | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99693373; called by muse, mutect2, varscan2
- ATXN1 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as rs1390386736, COSV55222203, COSV99787397; called by muse, mutect2, varscan2
- B3GAT1 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs745396903, COSV100438126; called by muse, mutect2, varscan2
- BAIAP2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1217192954, COSV58342406; called by muse, mutect2
- BAZ1A | c.625G>C p.A209P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100701201; called by muse, mutect2, varscan2
- BRCA1 | c.5401G>A p.G1801S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs587776492, COSV100524831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C12orf40 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100210573; called by muse, mutect2, varscan2
- C17orf78 | c.507C>T p.T169= | Splice Region (SNP) | VAF 19/35 reads (54%) | catalogued as rs747693501; called by muse, mutect2, varscan2
- C9orf72 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101186543, COSV101186548; called by muse, mutect2, varscan2
- CBFB | c.547T>C p.*183Qext*9 | Nonstop Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV99325905; called by muse, mutect2, varscan2
- CCPG1 | c.1310A>C p.K437T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99380627; called by muse, mutect2, varscan2
- CCT6A | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51904369, COSV99303670; called by muse, mutect2, varscan2
- CD1B | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs960498473, COSV63803732; called by muse, mutect2, varscan2
- CDH19 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100052065; called by muse, mutect2, varscan2
- CDK12 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.924); catalogued as COSV101420512, COSV70999258; called by muse, mutect2, varscan2
- CLEC4M | c.1088G>C p.S363T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99940778; called by muse, mutect2, varscan2
- CNNM2 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV100881749; called by muse, mutect2, varscan2
- CSMD1 | c.10258G>T p.G3420C (on ENST00000520002; = p.G3419C on NM_033225.6) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100152443; called by muse, mutect2, varscan2
- CSMD3 | c.10513T>A p.Y3505N (on ENST00000297405 / NM_001363185.1; = p.Y3336N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99843977; called by muse, mutect2, varscan2
- CTNNAL1 | c.1934C>G p.S645* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100336688; called by muse, mutect2, varscan2
- DEPDC5 | c.2300G>A p.R767H (on ENST00000400246; = p.R836H on NM_014662.5) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1396979413, COSV56708649; called by mutect2, varscan2
- DIP2B | c.1781T>G p.L594R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.949); catalogued as COSV99999153; called by muse, mutect2, varscan2
- DNAI1 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769177784, COSV99647073; called by muse, mutect2, varscan2
- DOCK2 | c.1756T>G p.S586A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99914513; called by muse, mutect2
- DPPA4 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs866863841, COSV100169614; called by muse, mutect2, varscan2
- EMC2 | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55207833, COSV99624454; called by muse, mutect2
- EPPK1 | c.3943G>T p.E1315* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101599930; called by muse, mutect2
- ERAP2 | c.1990C>T p.H664Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV65941035; called by muse, mutect2
- EXOC6 | c.1348G>T p.V450F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1267862274, COSV99592372; called by muse, mutect2
- FAN1 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV100756054; called by muse, mutect2, varscan2
- FCGR1A | c.770T>A p.L257* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | catalogued as COSV100977308; called by muse, mutect2, varscan2
- FCN2 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99391409; called by muse, mutect2, varscan2
- GALNT2 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795861; called by muse, mutect2, varscan2
- GAPT | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV59246946, COSV59247278; called by muse, mutect2
- GATM | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as COSV101188389; called by muse, mutect2, varscan2
- GCKR | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs747595070, COSV99254016; called by muse, mutect2, varscan2
- GDE1 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as COSV100783223; called by muse, varscan2
- GPCPD1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as rs544604483, COSV66830240; called by muse, mutect2, varscan2
- GPHN | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.368); catalogued as rs778183257, COSV100017357; called by muse, varscan2
- GPR101 | c.785T>C p.F262S | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as COSV99981573; called by muse, mutect2, varscan2
- GRIK1 | c.1248G>C p.K416N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.95); catalogued as COSV100413271; called by muse, mutect2, varscan2
- HDAC8 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.095); catalogued as COSV101002393; called by muse, mutect2, varscan2
- HECTD3 | c.1140G>C p.L380F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99870388; called by muse, mutect2, varscan2
- HIP1 | c.3061G>C p.G1021R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as COSV100418076; called by muse, mutect2
- HMG20A | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100287900; called by muse, mutect2, varscan2
- HOXD8 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497139; called by muse, mutect2
- HPS3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs775492008, COSV99937557; called by muse, mutect2, varscan2
- IKBKB | c.1611G>T p.M537I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100645798; called by muse, mutect2, varscan2
- IRX3 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100315388; called by muse, mutect2, varscan2
- ITGAV | c.2200C>T p.Q734* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99655511; called by muse, mutect2, varscan2
- KBTBD6 | c.1008G>C p.Q336H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101068845; called by muse, mutect2, varscan2
- KCNA4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100069192, COSV60254086; called by muse, mutect2, varscan2
- KCNK10 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56638745; called by muse, mutect2, varscan2
- KDM5B | c.2928G>C p.K976N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV99351214; called by muse, mutect2, varscan2
- KRI1 | c.1080G>C p.E360D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100470372; called by muse, mutect2, varscan2
- KRT18 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV101184094; called by muse, mutect2, varscan2
- KSR1 | c.847C>G p.L283V (on ENST00000644974 / NM_001367810.1; = p.L146V on NM_014238.2) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as COSV99260444; called by muse, mutect2, varscan2
- L3MBTL3 | c.1712G>C p.R571T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs749202131, COSV62386711; called by muse, mutect2, varscan2
- LEAP2 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99535261; called by muse, mutect2, varscan2
- LILRB1 | c.1394C>T p.P465L (on ENST00000427581; = p.P429L on NM_006669.6) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as rs376117202; called by muse, mutect2, varscan2
- LRRC31 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.111); catalogued as COSV52981676; called by muse, mutect2
- LTN1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1174628834, COSV100798130; called by muse, mutect2, varscan2
- LYPLAL1 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100859721, COSV65106200; called by muse, mutect2, varscan2
- LZTFL1 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV99944877; called by muse, mutect2, varscan2
- MAGEC3 | c.1133A>C p.D378A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV100025943; called by muse, mutect2, varscan2
- MCM8 | c.351_354del p.K118Efs*5 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs762416121; called by pindel, varscan2
- MCOLN1 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV99900784; called by muse, mutect2, varscan2
- MED14 | c.2770A>C p.I924L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.651); catalogued as COSV100247596; called by muse, mutect2, varscan2
- MICAL3 | c.3488A>T p.E1163V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV101490937; called by muse, mutect2, varscan2
- MICAL3 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV101490938; called by muse, mutect2, varscan2
- MSH3 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV54145597, COSV54153422; called by muse, mutect2, varscan2
- MUC16 | c.16597G>C p.D5533H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.227); catalogued as COSV101200951; called by muse, mutect2, varscan2
- MUSK | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99504857; called by muse, mutect2, varscan2
- NLRP5 | c.571T>G p.S191A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV101173837; called by muse, mutect2, varscan2
- NUAK1 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777232; called by muse, mutect2
- OCRL | c.1646A>C p.D549A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100843533; called by muse, mutect2, varscan2
- OPN1SW | c.474G>T p.W158C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975854; called by muse, varscan2
- OR4C13 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV73648663; called by muse, mutect2, varscan2
- OR8H1 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV100477294; called by muse, varscan2
- OR9A4 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs781803497, COSV101516510, COSV71886143; called by muse, mutect2, varscan2
- ORAI2 | c.409T>C p.S137P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100709960; called by muse, mutect2, varscan2
- PAPOLA | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV99354527; called by muse, mutect2
- PCDHB1 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100128346; called by muse, mutect2, varscan2
- PCDHGA4 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV99544444; called by muse, mutect2, varscan2
- PHC2 | c.1268G>A p.C423Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.459); catalogued as COSV99931301; called by muse, mutect2, varscan2
- PKHD1 | c.10129G>C p.E3377Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100584205; called by muse, mutect2, varscan2
- PKHD1L1 | c.11373C>A p.N3791K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV101006673, COSV65753839; called by muse, mutect2, varscan2
- POLA1 | c.2548G>C p.G850R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100985729; called by muse, mutect2, varscan2
- PPP1R26 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100778138; called by muse, mutect2, varscan2
- PPP4R4 | c.1473A>T p.E491D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100428916; called by muse, mutect2, varscan2
- PRRC2A | c.4316G>T p.R1439L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV101051146, COSV101051320; called by muse, mutect2, varscan2
- PSEN1 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1555350551, COSV99998028; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2063C>G p.A688G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99921591; called by muse, mutect2
- RAPGEF2 | c.1075A>T p.N359Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100031525; called by muse, mutect2, varscan2
- RASAL1 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.943); catalogued as rs867874711, COSV99922034; called by muse, mutect2, varscan2
- RETSAT | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1436770536, COSV99806198; called by mutect2, varscan2
- RIC8A | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100254895; called by muse, mutect2, varscan2
- RUFY3 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99887755; called by muse, mutect2, varscan2
- RYR3 | c.7241G>T p.R2414M (on ENST00000389232; = p.R2415M on NM_001036.6) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66810014; called by muse, mutect2, varscan2
- SELE | c.1462T>C p.C488R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100325053; called by muse, mutect2, varscan2
- SERINC3 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54855724; called by muse, mutect2, varscan2
- SERPINA4 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54068718, COSV54069076; called by muse, mutect2, varscan2
- SHISA5 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99604156; called by muse, mutect2, varscan2
- SKI | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV101049540; called by muse, mutect2
- SLC16A11 | c.1357C>T p.P453S (on ENST00000308009; = p.P429S on NM_153357.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100338730; called by muse, mutect2, varscan2
- SLC4A4 | c.808C>T p.L270= (on ENST00000264485 / NM_001098484.3; = p.L226= on NM_003759.4) | Splice Region (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99141417; called by muse, mutect2, varscan2
- SLC9A3R2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1175709490, COSV99526475; called by muse, mutect2, varscan2
- SNAI1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99723997; called by muse, mutect2, varscan2
- SNRNP48 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60941142; called by muse, mutect2, varscan2
- SOBP | c.832A>C p.T278P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100433343; called by muse, mutect2, varscan2
- SORCS1 | c.3110T>A p.L1037Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99549216; called by muse, mutect2, varscan2
- SPAG6 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100510432; called by muse, mutect2, varscan2
- SPRED1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54437401, COSV54439454; called by muse, mutect2, varscan2
- STAU2 | c.547C>A p.P183T (on ENST00000524300 / NM_001164380.2; = p.P151T on NM_014393.2) | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100869213; called by muse, mutect2, varscan2
- SVIL | c.4191G>C p.K1397N (on ENST00000355867 / NM_021738.3; = p.K971N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV100881471; called by muse, mutect2, varscan2
- SYNJ1 | c.1730G>C p.G577A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100449562; called by muse, mutect2, varscan2
- SYTL1 | c.1135G>C p.E379Q (on ENST00000543823; = p.E367Q on NM_032872.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV100539538, COSV100539663; called by muse, mutect2, varscan2
- SYTL2 | c.1808C>T p.S603F (on ENST00000528231 / NM_001162951.2; = p.S1892F on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100314722; called by muse, mutect2, varscan2
- TBC1D25 | c.1681T>A p.S561T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV65123988; called by muse, mutect2, varscan2
- TCEAL5 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs778829479, COSV65502650; called by muse, mutect2, varscan2
- TNRC6A | c.5813G>A p.R1938Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1349998586, COSV59366812; called by muse, mutect2, varscan2
- TNRC6C | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV100050529; called by muse, mutect2, varscan2
- TOPBP1 | c.3832C>G p.Q1278E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99605714; called by muse, mutect2, varscan2
- TRPA1 | c.1699C>T p.L567F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084920; called by muse, mutect2, varscan2
- TRPC7 | c.1614C>G p.I538M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100725894; called by muse, mutect2, varscan2
- TSPYL1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63993912; called by muse, mutect2, varscan2
- TTC37 | c.489G>C p.L163F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100706803, COSV62455397; called by muse, mutect2, varscan2
- TUT1 | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as COSV99545526; called by muse, mutect2, varscan2
- UBE3C | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV100780051; called by muse, mutect2, varscan2
- UBR2 | c.2704G>A p.G902R | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100867501; called by muse, mutect2, varscan2
- UROC1 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99332195; called by muse, mutect2, varscan2
- USP37 | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99294764; called by muse, mutect2, varscan2
- USP51 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV72351419; called by muse, mutect2, varscan2
- WDR47 | c.1810G>C p.E604Q (on ENST00000369962 / NM_001142551.2; = p.E605Q on NM_014969.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728416, COSV100728465; called by mutect2, varscan2
- ZDHHC24 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100130692; called by muse, mutect2, varscan2
- ZNF211 | c.218G>A p.G73D (on ENST00000347302 / NM_198855.4; = p.G86D on NM_006385.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs749758158, COSV99560429; called by muse, mutect2, varscan2
- ZNF264 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs932306455, COSV99567397; called by muse, mutect2, varscan2
- ZNF485 | c.837C>G p.F279L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100700272; called by muse, mutect2
- ZNF610 | c.4C>G p.L2V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV100016971; called by muse, mutect2, varscan2
- ZWINT | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs780802886, COSV100571548; called by muse, mutect2, varscan2
- ADAM29 | c.964del p.T322Lfs*13 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- FGFR3 | c.615+1G>T p.X205_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- HOXB3 | c.1180_1195del p.P394Dfs*30 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- SOAT2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- ARMCX2 | c.1848C>T p.H616= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100168251; called by muse, mutect2
- ASH2L | c.447C>A p.V149= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV51699514, COSV99167032; called by muse, mutect2, varscan2
- C12orf40 | c.744T>C p.C248= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs575303534, COSV100210574; called by muse, mutect2, varscan2
- CEP290 | c.435T>C p.N145= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100469486; called by muse, mutect2, varscan2
- COG7 | c.1179C>T p.H393= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs745699956, COSV100207750; called by muse, mutect2, varscan2
- CTTNBP2 | c.1938G>C p.L646= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99354628; called by muse, mutect2, varscan2
- CYP39A1 | c.390C>G p.V130= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV51498257, COSV99242642; called by muse, varscan2
- DNAH10 | c.12081C>T p.L4027= (on ENST00000409039; = p.L3966= on NM_207437.3) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1566118225, COSV101292501, COSV69000063; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1134T>A p.G378= (on ENST00000361735 / NM_015935.5; = p.G292= on NM_014955.3) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100675793, COSV100675999; called by muse, mutect2, varscan2
- FAM83A | c.495G>C p.L165= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV99414510; called by muse, mutect2, varscan2
- FAT1 | c.10797G>C p.L3599= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV101499578; called by muse, mutect2, varscan2
- GAA | c.2658G>C p.V886= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100163451; called by muse, mutect2, varscan2
- GGT7 | c.1653G>C p.A551= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs753110256, COSV100321981, COSV100322143, COSV60540628; called by muse, mutect2, varscan2
- GRIPAP1 | c.1461C>T p.L487= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100904363; called by muse, mutect2
- GZMM | c.630C>T p.P210= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1253761388, COSV99198848, COSV99198866; called by muse, mutect2, varscan2
- H4C8 | c.273G>A p.L91= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99175506; called by muse, mutect2, varscan2
- HES4 | c.162C>G p.L54= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100515130, COSV59242962; called by muse, mutect2
- HIPK3 | c.2754G>C p.L918= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100305984; called by muse, mutect2, varscan2
- HORMAD1 | c.690A>G p.R230= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100464371; called by muse, mutect2, varscan2
- KCTD11 | c.306C>T p.F102= (on ENST00000333751 / NM_001363642.1; = p.F63= on NM_001002914.2) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1226141632, COSV99341907; called by muse, mutect2, varscan2
- KIAA0513 | c.417C>T p.Y139= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1419451074, COSV99261194; called by muse, mutect2, varscan2
- KIF2B | c.873C>T p.I291= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52130684; called by muse, mutect2
- MMP11 | c.249C>T p.P83= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs144178537, COSV53157500; called by muse, mutect2, varscan2
- MVB12B | c.288C>T p.F96= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100753093; called by muse, mutect2, varscan2
- MYO1F | c.2190G>C p.R730= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100596978; called by muse, mutect2, varscan2
- NEK4 | c.1092C>T p.S364= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs765071264, COSV99237658; called by muse, mutect2, varscan2
- OR2T11 | c.219C>T p.T73= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100424920; called by muse, mutect2, varscan2
- OR4K5 | c.576T>G p.S192= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100262565; called by muse, mutect2, varscan2
- OSCP1 | c.48G>A p.E16= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV52487422; called by muse, mutect2, varscan2
- PIWIL4 | c.2556G>T p.L852= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100133370; called by muse, mutect2, varscan2
- PPARGC1A | c.1728G>A p.R576= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99338455; called by muse, mutect2, varscan2
- PRKDC | c.10125G>C p.A3375= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100042290, COSV58062817; called by muse, mutect2, varscan2
- PSD | c.2625C>G p.P875= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs375125392, COSV99193631; called by muse, mutect2, varscan2
- PSORS1C2 | c.9C>T p.L3= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99456259; called by muse, mutect2, varscan2
- RASSF4 | c.189G>C p.L63= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV100024479; called by muse, mutect2, varscan2
- RNF215 | c.831G>A p.A277= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs755036120, COSV99306647; called by muse, mutect2, varscan2
- SFTPA2 | c.375C>T p.L125= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100958830; called by muse, mutect2, varscan2
- SIGLEC1 | c.1035C>G p.V345= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV52470692, COSV99170150; called by muse, mutect2, varscan2
- SIRPA | c.267G>T p.R89= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as COSV100605322; called by muse, mutect2, varscan2
- SLC45A1 | c.222C>T p.D74= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99239461; called by muse, mutect2, varscan2
- SMG8 | c.699G>C p.L233= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99958781; called by muse, mutect2, varscan2
- SRSF11 | c.462A>G p.P154= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV63937152; called by muse, mutect2, varscan2
- TAS1R1 | c.429G>A p.V143= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100063378; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1524A>G p.K508= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100389840; called by muse, mutect2, varscan2
- UBE2M | c.279G>C p.V93= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99448318; called by muse, mutect2, varscan2
- ZNF217 | c.2619C>T p.L873= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs756974353, COSV56593836; called by muse, mutect2, varscan2
- ZNF264 | c.1551G>C p.G517= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99567401; called by muse, mutect2, varscan2
- ZNF70 | c.969C>T p.L323= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV59533187; called by muse, mutect2, varscan2
- COPS9 | chr2:240126607 C>G | 3'Flank (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100217118; called by muse, mutect2, varscan2
